Somatic mutation profile of tumor specimen 0DM8UD from CCDI case PBCABM, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 12.5 years (4,570 days).
Specimen 0DM8UD: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 86fc0ae2-ecce-4488-9ad4-e75e004baed1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DM8U5 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/35cf35f1-5555-4170-ba81-25383fb11037

The open-access MAF lists 23 somatic variants for this specimen: 18 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 3, Intron 2, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FAM171B | c.2336C>T p.S779L | Missense Mutation (SNP) | VAF 528/1230 reads (43%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.45); catalogued as rs1199502753, COSV59005583; called by muse, mutect2, varscan2
- ITGB4 | c.176G>A p.R59Q | Missense Mutation (SNP) | VAF 102/1316 reads (8%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.72); catalogued as rs201532846, COSV52332352; called by muse, mutect2
- OR4S1 | c.141C>G p.I47M | Missense Mutation (SNP) | VAF 27/1005 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV100180246, COSV60680413; called by muse, mutect2
- POFUT1 | c.301C>T p.R101W | Missense Mutation (SNP) | VAF 499/3010 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs770978581, COSV65260262; called by muse, mutect2, varscan2
- PRDM5 | c.1672C>T p.R558* | Nonsense Mutation (SNP) | VAF 588/3009 reads (20%) | catalogued as rs1490743354, COSV53358821, COSV53369111; called by muse, varscan2
- SH3TC1 | c.4006C>T p.R1336C | Missense Mutation (SNP) | VAF 995/2308 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.188); catalogued as rs780527919, COSV55287347; called by muse, mutect2, varscan2
- TM4SF1 | c.133C>G p.R45G | Missense Mutation (SNP) | VAF 1136/2769 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.369); catalogued as COSV59525031; called by muse, mutect2, varscan2
- ZFP36 | c.32C>A p.A11D (on ENST00000594442; = p.A5D on NM_003407.5) | Missense Mutation (SNP) | VAF 367/924 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.039); catalogued as COSV50529093; called by muse, mutect2, varscan2
- ZNF716 | c.31C>T p.R11* | Nonsense Mutation (SNP) | VAF 682/3609 reads (19%) | catalogued as rs1554321361, COSV70779933; called by muse, mutect2, varscan2
- ARAP2 | c.4486A>C p.K1496Q | Missense Mutation (SNP) | VAF 595/3347 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- CSF2RB | c.2513A>T p.K838I | Missense Mutation (SNP) | VAF 584/1242 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DENND4B | c.101C>T p.P34L | Missense Mutation (SNP) | VAF 63/1479 reads (4%) | SIFT tolerated (0.05); PolyPhen benign (0.034); called by muse, mutect2
- FAT3 | c.4894A>G p.T1632A | Missense Mutation (SNP) | VAF 1071/2427 reads (44%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KLK15 | c.719C>G p.T240S | Missense Mutation (SNP) | VAF 66/1512 reads (4%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.979); called by muse, mutect2
- MYCBP2 | c.9161A>C p.E3054A (on ENST00000357337; = p.E3092A on NM_015057.5) | Missense Mutation (SNP) | VAF 725/1684 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- RNF19B | c.1762G>A p.E588K | Missense Mutation (SNP) | VAF 850/1908 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- SNED1 | c.1436G>T p.R479I | Missense Mutation (SNP) | VAF 99/926 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- TG | c.8284G>C p.G2762R | Missense Mutation (SNP) | VAF 146/3290 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.347); called by muse, mutect2
- NLRP5 | c.714C>T p.H238= | Silent (SNP) | VAF 944/2384 reads (40%) | catalogued as rs748328723; called by muse, mutect2, varscan2
- SEPTIN12 | c.792G>T p.L264= | Silent (SNP) | VAF 645/1538 reads (42%) | called by muse, mutect2, varscan2
- UTP11 | c.477G>A p.P159= | Silent (SNP) | VAF 867/1909 reads (45%) | catalogued as rs746984416; called by muse, mutect2, varscan2
- ELAPOR1 | c.1042-578G>A | Intron (SNP) | VAF 345/875 reads (39%) | called by muse, mutect2, varscan2
- PPP1R9A | c.2757+768A>T | Intron (SNP) | VAF 534/1813 reads (29%) | called by muse, varscan2
